Somatic mutation profile of tumor specimen 0DCM1I from CCDI case PBBMPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 17.0 years (6,226 days).
Specimen 0DCM1I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad2edb6d-91b9-415e-b04b-6b153664b573.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM1D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c84cdeb6-e446-4cc3-a4f0-699b6790628c

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2orf42 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 76/1286 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs777005211; called by muse, mutect2
- SDR16C5 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 97/484 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs755734218, COSV58126752; called by muse, mutect2, varscan2
- BRAF | c.1629_1637dup p.V544_R546dup (on ENST00000288602 / NM_001374244.1; = p.V504_R506dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 132/512 reads (26%) | called by mutect2, varscan2
- PARD6B | c.914A>G p.Q305R | Missense Mutation (SNP) | VAF 198/1032 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGQ | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2
- SEC16A | c.6803C>G p.S2268C | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- NREP | c.21C>T p.L7= | Silent (SNP) | VAF 144/699 reads (21%) | catalogued as COSV57405986; called by muse, mutect2, varscan2
